Somatic mutation profile of tumor specimen TCGA-YU-A90Y-01A (aliquot TCGA-YU-A90Y-01A-11D-A435-10) from TCGA case TCGA-YU-A90Y, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Dead; Primary diagnosis: Embryonal carcinoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 23.2 years (8,460 days).
Specimen TCGA-YU-A90Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13a5c6aa-49a3-4dc4-9a2a-1befe3d0fc65.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YU-A90Y-10A (Blood Derived Normal), aliquot TCGA-YU-A90Y-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/36d2c73c-eb09-466a-aeb0-718fa85628a2

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Nonsense Mutation 3, Silent 3, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SYNE1 | c.17167C>T p.Q5723* (on ENST00000367255 / NM_182961.4; = p.Q5652* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 4/46 reads (9%) | catalogued as rs886044380; ClinVar: likely pathogenic; called by muse, mutect2
- ATM | c.2644A>G p.I882V | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746424711; called by muse, mutect2, varscan2
- CPN2 | c.761C>A p.T254K | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0.017); catalogued as COSV60470445; called by muse, mutect2, varscan2
- EXOC3L4 | c.484G>T p.E162* | Nonsense Mutation (SNP) | VAF 23/67 reads (34%) | catalogued as COSV66295949; called by muse, mutect2, varscan2
- PSIP1 | c.935_937del p.A312del | In Frame Del (DEL) | VAF 36/174 reads (21%) | catalogued as rs1289336306; called by pindel, varscan2
- ZNF697 | c.970G>C p.E324Q | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as COSV70284224; called by muse, mutect2
- CCDC43 | c.305C>G p.A102G | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); called by muse, mutect2
- CCNT2 | c.329G>C p.C110S | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.249); called by muse, mutect2
- EVA1A | c.349G>T p.E117* | Nonsense Mutation (SNP) | VAF 33/146 reads (23%) | called by muse, mutect2, varscan2
- GRB10 | c.1484A>T p.H495L (on ENST00000398812; = p.H449L on NM_001001549.3) | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MMP11 | c.1267C>A p.P423T | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RNPC3 | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- TAOK3 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- REV3L | c.654A>G p.E218= | Silent (SNP) | VAF 36/135 reads (27%) | called by muse, mutect2, varscan2
- TXLNB | c.1116C>T p.S372= | Silent (SNP) | VAF 28/136 reads (21%) | called by muse, mutect2, varscan2
- UTRN | c.2475C>T p.S825= | Silent (SNP) | VAF 32/110 reads (29%) | called by muse, mutect2, varscan2
- ACAT1 | c.-34C>A | 5'UTR (SNP) | VAF 13/47 reads (28%) | called by muse, mutect2
